CCDI case PBCWBB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/2c1e5003-ac2b-47b9-b070-d84b6ba942ed

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0E18HK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E18HQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E18I7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
